CCDI case PBBPVW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2e4183d2-881b-40c9-a5ad-149340976cc2

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.3 years (3,746 days).

Biospecimens (3 samples)
- Sample 0DECX1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DECXB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DECXG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
